Gene-level copy-number profile of tumor specimen HTMCP-03-06-02013-01A from CGCI case HTMCP-03-06-02013, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIA2; Tumor grade: G3; Age at diagnosis: 50.8 years (18,551 days).
Specimen HTMCP-03-06-02013-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 586d3dc0-0e65-4308-9ee2-63d43f1de70d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02013-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,231 have no estimate.
https://portal.gdc.cancer.gov/files/1f807fa5-3f87-4c0e-ab24-b1a56ccbb0b4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 3,563; copy number 2: 37,848; copy number 3: 11,019; copy number 4: 5,827; copy number 5: 122; copy number 6: 1.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,898,423–140,899,106, 1 gene (within-gene range 0–2): LRRC57P1.
- chr17:18,426,861–18,551,705, 11 genes (within-gene range 0–1): KRT17P2, KRT16P1, KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 123 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:72,301,472–72,301,829, 1 gene, copy number 6: RPL31P12.
- chr1:143,975,087–145,708,148, 47 genes, copy number 5: SRGAP2D, IGKV1OR1-1, AC244015.1, AC244015.2, LINC02802, RNA5SP529, DRD5P2, AC245595.1, PPIAL4E, AC246785.4, RNVU1-15, AC246785.3, AC246785.2, NBPF15, PFN1P6, AC246785.1, RNVU1-26, RNVU1-2A, RNVU1-28, PPIAL4F, LINC01632, FP700111.1, FP700107.1, RNA5SP59, FP700111.2, FP700111.3, SRGAP2B, AC242498.1, FAM72D, LINC01145, RNU1-153P, AC241585.2, AC241585.1, PPIAL4D, AC245014.2, RNVU1-14, AC245014.3, AC245014.1, NBPF20, PFN1P3, RNU1-154P, RNVU1-31, AC239860.2, AC239860.1, NBPF25P, GPR89A, PDZK1.
- chr7:38,239,580–38,249,572, 1 gene, copy number 5: TRGC2.
- chr7:38,256,337–38,330,935, 13 genes, copy number 5 (within-gene range 3–5): TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8.
- chr14:22,132,553–22,501,663, 54 genes, copy number 5: TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41, TRAJ40, TRAJ39.
- chr14:22,547,506–22,552,156, 1 gene, copy number 5: TRAC.
- chr21:38,805,183–38,956,467, 6 genes, copy number 5: ETS2, AP001042.1, AP001042.2, AP001043.1, SNORA62, RPSAP64.

Autosomal genes at a single copy (total copy number 1): 2,099. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
